TCGA case TCGA-HQ-A5NE — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e053a911-2202-4c1f-bc93-904e26564e79

Demographics
Sex at birth: male; Country of residence at enrollment: Canada; Age at index: 56 years; Vital status: Dead; Days to death: 370 days (1.0 years).

Diagnoses (4)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,647 days); Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 370 days (1.0 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 5; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 238 days; Days to treatment end: 245 days; Treatment dose: 20 Gy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 57.1 years (20,858 days); Days to diagnosis: 211 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Renal pelvis. Age at diagnosis: 57.1 years (20,858 days); Days to diagnosis: 211 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for progressive disease; Surgery, NOS, for recurrent disease.
4. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Liver. Age at diagnosis: 57.1 years (20,858 days); Days to diagnosis: 211 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 211 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Renal pelvis; Days to recurrence: 211 days.
- Day 211 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Renal pelvis; Days to progression: 211 days.
- Day 211 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 211 days.
- Day 211 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 211 days.
- Days to follow up: 250 days; Disease response: With Tumor.
- Days to follow up: 370 days (1.0 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 175 cm; BMI: 20.2.

Exposures
- Occupation type: Car, Van and Motorcycle Drivers.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 80.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HQ-A5NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 330 mg.
  Slide TCGA-HQ-A5NE-01A-01-TS1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 65; Percent normal cells: 4; Percent necrosis: 5; Percent stromal cells: 46; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
- Sample TCGA-HQ-A5NE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HQ-A5NE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: unemployed; Occupation primary: taxi driver; Occupation primary industry: taxi service; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 370 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 370 days; disease-free interval: event (new tumor event after initially disease-free), 211 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 211 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HQ-A5NE-01A-12D-A288-01): tumor purity 0.26, ploidy 4.55, whole-genome doublings 2.
